Somatic mutation profile of tumor specimen 0DR6YD from CCDI case PBCFSP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 12.6 years (4,616 days).
Specimen 0DR6YD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16a331e8-b704-464e-b233-13cf1e5224a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR6Y4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b47f26ec-d794-44bc-ad4b-41aee2055fe2

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, 5'UTR 2, Silent 2, RNA 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYNC1H1 | c.2147G>A p.R716H | Missense Mutation (SNP) | VAF 206/441 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as rs759802064, COSV64134710; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ERMP1 | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 432/932 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs1418986910, COSV53037406; called by muse, mutect2, varscan2
- ILDR2 | c.1532C>T p.P511L | Missense Mutation (SNP) | VAF 183/377 reads (49%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as rs759780016; called by muse, mutect2, varscan2
- POLD1 | c.742G>A p.V248I | Missense Mutation (SNP) | VAF 172/417 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as rs538267691; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 44/1863 reads (2%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CBFA2T2 | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 508/1120 reads (45%) | called by muse, mutect2, varscan2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 39/1238 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- CENPF | c.9101A>G p.E3034G | Missense Mutation (SNP) | VAF 480/1051 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- KRT76 | c.1566C>G p.S522R | Missense Mutation (SNP) | VAF 482/1019 reads (47%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, varscan2
- ZNF423 | c.3044G>T p.C1015F (on ENST00000563137 / NM_001379286.1; = p.C1007F on NM_015069.4) | Missense Mutation (SNP) | VAF 209/392 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- CA4 | c.924C>G p.A308= | Silent (SNP) | VAF 210/671 reads (31%) | catalogued as COSV99958173; called by muse, mutect2, varscan2
- WDR45B | c.918C>T p.N306= | Silent (SNP) | VAF 207/678 reads (31%) | catalogued as rs368935950; ClinVar: likely benign; called by muse, mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 22/470 reads (5%) | called by muse, mutect2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 16/430 reads (4%) | called by muse, mutect2
- PPP1R42 | c.-130T>C | 5'UTR (SNP) | VAF 175/396 reads (44%) | catalogued as rs898076477; called by muse, mutect2, varscan2
- SCT | c.-25T>C | 5'UTR (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
